Surgical pathology report (de-identified scan), TCGA case TCGA-SI-AA8C, project TCGA-SARC (Sarcoma), tissue source site Washington University St. Louis, specimen TCGA-SI-AA8C-01A (Primary Tumor).

[page 1 of 4]
Patient Name: [REDACTED]
DOB: [REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT FINAL WITH ADDENDUM

Patient Name: [REDACTED]	Service: Orthopedic Surgery	Accession: [REDACTED]
Address: [REDACTED]	Location: [REDACTED]	Taken: [REDACTED]
Gender: [REDACTED]	MRN: [REDACTED]	Received: [REDACTED]
DOB: [REDACTED]	Hospital #: [REDACTED]	Accessioned: [REDACTED]
	Patient Type: [REDACTED]	Reported: [REDACTED]

Physician(s):

DIAGNOSIS:

SOFT TISSUE, LEFT THIGH, BIOPSY (FS1)
- MALIGNANT PERIPHERAL NERVE SHEATH TUMOR

SOFT TISSUE, LEFT THIGH, MASS, EXCISION
- MALIGNANT PERIPHERAL NERVE SHEATH TUMOR, HIGH GRADE, III/III
- WITH FOCAL CARTILAGINOUS DIFFERENTIATION
- TUMOR MEASURES 7.5 CM IN GREATEST DIMENSION
- TUMOR FOCALLY EXTENDS TO INKED MEDIAL MARGIN
- SEE COMMENT

ICD-O 3

Tumor, peripheral nerve sheath malignant
Site: @ Thigh NOS
954813
149.2
05/30/14

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

--Report Electronically Reviewed and Signed Out by

Intraoperative Consultation:

FS1: Soft tissue, left thigh, biopsy
- "Spindle cell neoplasm, likely sarcoma,"

Microscopic Description and Comment:

Sections show a high grade spindle cell malignant neoplasm, arising in the background of a diffuse neurofibroma. There is focal cartilaginous differentiation. Numerous mitotic figures are present, with extensive tumor necrosis. The tumor focally extends to inked medial margin, less than 0.1 cm (section B9). Immunoperoxidase stains were performed. The tumor cells show diffuse positive staining for vimentin with patchy staining for S-100 protein and collagen IV. The p53 shows positive staining in a subset of tumor cells. The tumor cells are negative for cytokeratin. Given the patient's history of neurofibromatosis type 1, the morphologic features and immunohistochemical staining

[page 2 of 4]
Patient Name: [REDACTED]

DOB: [REDACTED]

SURGICAL PATHOLOGY REPORT

profile are consistent with a malignant peripheral nerve sheath tumor, high grade.

Select slides were reviewed with Dr [REDACTED] and he concurs with the diagnosis.

History:

The patient is [REDACTED] who has a known history of neurofibromatosis type I who presents with a large soft tissue mass in the left medial thigh. Preoperative imaging study shows this to be an approximately 10 x 8 cm mass with signal characteristics consistent with malignant peripheral nerve sheath tumor. Operative procedure: Open biopsy, wide mass excision of left thigh.

Specimen(s) Received:

A: LEFT THIGH

B: LEFT THIGH MASS

Gross Description:

The specimens are received in two formalin-filled containers, each labeled [REDACTED]. The first container is labeled "left thigh biopsy." It holds a green tissue cassette marked "FS1." There are multiple core biopsies that are wrapped in tissue paper (0.6 to 1.2 cm in greatest dimensions). The wrapped tissue is transferred to A1. Jar 0.

The second container is labeled "left thigh mass - stitch proximal." It holds a 970 gram, 18 x 15 x 9 cm partially inked, previously opened specimen. There is a 7.5 x 2.0 cm spindle-shaped attached piece of skin. The specimen is previously inked blue on the lateral surface, and there is a single section through the center of the mass. The mass is approximately 7.5 x 7 x 7 cm. It is well demarcated and appears to have a capsule. The mass is soft, tan brown and has abundant necrosis and some cystic appearing spaces. The specimen is inked as follows: Blue is medial and lateral margins, Black is deep margin, Yellow is proximal margin, and Green is distal margin. The nearest margin is deep, approximately 0.5 cm away. The medial and lateral margins are 1.2 cm away. The proximal margin is 3.0 cm away and the distal margin is 6.5 cm away. The skin is 4.0 cm from the edge of the mass. Labeled B1 and B2 - Representative sections of tumor, from periphery; B3 - proximal margin (shave); B4 - distal margin (shave); B5 - mass with lateral margin; B6 - mass at nearest approach to deep margin; B7 - mass with lateral margin; B8 - representative section at overlying skin; B9 through B14 - representative section of mass. Jar 3.

SYNOPTIC REPORTING FORM - SOFT TISSUE -- RESECTION FOR SARCOMA

TUMOR LOCATION

The tumor is located in the extremity and superficial trunk

HISTOPATHOLOGIC TYPE

The principal histologic pattern is malignant peripheral nerve sheath tumor

HISTOLOGIC GRADE (G)

The lesion is poorly differentiated-High Grade (G3)

SAMPLED SPECIMEN MARGINS

The tumor extends to the medial margin

PRIMARY TUMOR (T)

Tumor more than 5 cm in greatest dimension and deep (T2b)

REGIONAL LYMPH NODES (N)

Regional lymph nodes cannot be assessed (NX)

DISTANT METASTASES (M)

Distant metastasis cannot be assessed (MX)

[page 3 of 4]
Patient Name [REDACTED]

DOB: [REDACTED]

SURGICAL PATHOLOGY REPORT

STAGE GROUPING:
pT2b/NX/MX

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Addenda/Procedures

Addendum Ordered:
Addendum Complete:
Addendum Signed Out:

Status: Signed Out
By:

Addendum Diagnosis

Fluorescence In-situ hybridization (FISH) Results:

Specimen [REDACTED]

NEGATIVE - FISH result for MLL gene rearrangement

NEGATIVE - FISH result for ALK gene rearrangement

nuc ish(MLLx1)(124/200)/(MLLx2)(87/200)

nuc ish(ALKx4-5)(21/200)/(ALKx3)(42/200)/(ALKx2)(121/200)

Addendum Comment

MLL-BA FISH

FISH was performed utilizing a commercial MLL (11q23) break apart probe set. In this particular case, a split of red and green signals was not detected in 200 interphase cells examined. Therefore, there is no evidence for a MLL-containing chromosomal rearrangement. Loss of MLL was noted with 1 copy seen in 62%, the significance of which, if any, is unclear.

ALK-BA FISH

FISH for ALK gene rearrangement at chromosomal locus 2p23 was performed utilizing Break Apart FISH probe kit (IVD) (-). ALK Break Apart FISH Probe Kit is a qualitative test to detect rearrangements involving the ALK gene via fluorescence in situ hybridization (FISH) in formalin-fixed paraffin-embedded (FFPE) non-small cell lung cancer (NSCLC) tissue specimens to aid in identifying those patients eligible for treatment with XALKORI (crizotinib). The laboratory follows the manufacturer's guidelines in the processing and analysis of this FDA-approved IVD FISH probe.

Positive for gene rearrangement: $\geq 15\%$ of a minimum of 100 interphase cells with positive signal pattern

Negative for gene rearrangement: $< 15\%$ of a minimum of 100 interphase cells with positive signal pattern

Comment: This case was negative for ALK gene rearrangement according to the above criterion. A gain of ALK was noted; 3~5 copies of ALK were observed in 31.5% of the 200 nuclei examined, the significance of which, if any, is unclear.

Reference:

Fluorescence in-situ hybridization analysis was performed in the

See

for original FISH report.

Lab at

and electronically signed out by Dr.

[page 4 of 4]
Patient Name: [REDACTED]
DOB: [REDACTED]

SURGICAL PATHOLOGY REPORT

Addendum Ordered:
Addendum Complete:
Addendum Signed Out:

Status: Signed Out
By:

Addendum Comment:

Case Number: [REDACTED]
Specimen ID: [REDACTED]

At the request of [REDACTED], a specimen was sent for the [REDACTED]
and results were reported to the ordering physician.

Surgical Pathology report is available on-line on

END OF REPORT

Source: NCI Genomic Data Commons file b61ebca1-2425-4760-97f9-b4b7ffdcf57c (TCGA-SI-AA8C.F665C4CF-4C61-46F1-A979-5CEC4944081F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).